Gene-level copy-number profile of tumor specimen TCGA-DX-A3UE-01A from TCGA case TCGA-DX-A3UE, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-DX-A3UE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.1f0dd9d9-3c82-4bee-adc1-7f20794a3fe7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3UE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7454ea16-96d4-4c01-8d70-7136676fd196

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 7,811; copy number 2: 49,147; copy number 3: 2,780; copy number 4: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3UE-01A-11D-A306-01): tumor purity 0.93, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:129,278,251–132,976,354, 50 genes: AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, AC016816.1, MIR378C, TCERG1L, TCERG1L-AS1, LINC01164, AL450307.1, AL607033.1, FP565171.1, PPP2R2D, BNIP3, AL162274.2, AL162274.1, AL162274.3, JAKMIP3, AL512622.1, DPYSL4, STK32C, LRRC27, PWWP2B, AL451069.2, AL451069.3, LINC02870, AL451069.1, LINC01165, INPP5A, NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,811. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
